Gene-level copy-number profile of tumor specimen TCGA-EP-A2KA-01A from TCGA case TCGA-EP-A2KA, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 52.6 years (19,214 days).
Specimen TCGA-EP-A2KA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.94a8c286-62ca-4837-bccc-536831def5db.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EP-A2KA-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 851 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/abf011d2-424a-450b-83c5-d0d53c1c33ae

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 1,335; copy number 2: 40,507; copy number 3: 13,050; copy number 4: 2,468; copy number 5: 1,568; copy number 6: 442; copy number 7: 271; copy number 8: 62; copy number 10: 3; copy number 11: 41; copy number 12: 25.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EP-A2KA-01A-11D-A182-01): tumor purity 0.62, ploidy 2.34, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,412 genes in 80 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:76,867,480–77,879,539, 20 genes, copy number 5 (within-gene range 4–5): ST6GALNAC5, MIR7156, AL035409.2, AL035409.1, PIGK, AC113935.1, AC093433.1, AC093433.2, AK5, AC095030.1, RNU7-8P, AC093575.1, ZZZ3, RNA5SP20, RN7SL370P, USP33, ACTG1P21, MIGA1, RNA5SP21, AC138392.1.
- chr1:143,343,180–148,255,012, 164 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr1:149,903,318–150,964,744, 47 genes, copy number 5 (within-gene range 3–5): SV2A, SF3B4, MTMR11, OTUD7B, AC244033.2, AC244033.1, VPS45, PLEKHO1, AC242988.2, RN7SL480P, ANP32E, RNU2-17P, AC242988.1, CA14, APH1A, C1orf54, CIART, MRPS21, PRPF3, RPRD2, TARS2, MIR6878, ECM1, FALEC, ADAMTSL4-AS2, ADAMTSL4, MIR4257, ADAMTSL4-AS1, MCL1, RN7SL473P, RN7SL600P, AL356356.1, ENSA, U4, GOLPH3L, HORMAD1, RNU6-1042P, CTSS, AL356292.1, CTSK, UBE2D3P3, ARNT, RNU6-1309P, RPS27AP6, CTXND2, CYCSP51, SETDB1.
- chr1:153,678,688–155,244,699, 100 genes, copy number 7 (within-gene range 3–7) (broad region; genes not listed).
- chr1:155,609,776–157,898,256, 102 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr1:158,523,672–160,428,670, 86 genes, copy number 6 (broad region; genes not listed).
- chr1:173,351,689–176,207,286, 54 genes, copy number 5: AL645568.2, AL645568.1, PRDX6-AS1, PRDX6, SLC9C2, AL139142.1, AL139142.2, ANKRD45, TEX50, KLHL20, BX248409.1, RN7SKP160, CENPL, Y_RNA, DARS2, GAS5, GAS5-AS1, ZBTB37, SERPINC1, RNA5SP67, RC3H1, RNA5SP68, RC3H1-IT1, LINC02776, RPL30P1, RABGAP1L-DT, RABGAP1L, AL022400.1, GPR52, BANF1P4, NDUFAF4P4, Z99127.2, RABGAP1L-IT1, Z99127.1, RABGAP1L-AS1, RNU6-307P, Z99127.3, CACYBP, MRPS14, Y_RNA, ENTR1P2, TNN, KIAA0040, AL008626.1, RPS29P4, Z94057.1, TNR, TNR-IT1, LINC01657, LINC02803, RPS29P5, COP1, SCARNA3, AL590723.1.
- chr1:196,582,413–197,935,478, 25 genes, copy number 6: MIR4735, CFH, CFHR3, CFHR1, BX248415.1, CFHR4, CFHR2, AL139418.1, CFHR5, F13B, ASPM, SEPTIN14P12, ZBTB41, AL513325.1, CRB1, MRPS21P3, AL136322.1, DENND1B, Y_RNA, EEF1A1P32, AL365258.2, FAM204BP, AL365258.1, C1orf53, LHX9.
- chr1:219,962,652–221,742,089, 42 genes, copy number 6: U3, EPRS1, BPNT1, IARS2, MIR215, MIR194-1, RPS15AP12, RAB3GAP2, MIR664A, SNORA36B, SNX2P1, KF455155.1, MORF4L1P1, AURKAP1, XRCC6P3, AL451081.2, AL451081.1, AC096644.3, AC096644.2, AC096644.1, PRELID3BP1, LINC02779, MARK1, RN7SL464P, HDAC1P2, C1orf115, MTARC2, MTARC1, AL445423.3, RNU6ATAC35P, AL445423.2, AL445423.1, LINC01352, HLX-AS1, HLX, AL445466.1, LINC02817, AL360013.2, AL360013.3, AL360013.1, AL360013.4, DUSP10.
- chr1:245,614,773–247,761,255, 70 genes, copy number 5–7 (within-gene range 3–7) (broad region; genes not listed).
- chr2:9,671,875–11,676,925, 62 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr3:172,039,578–174,286,644, 24 genes, copy number 6–11 (within-gene range 2–11): FNDC3B, RPS27AP8, RN7SL141P, AC092964.1, BZW1P1, GHSR, TNFSF10, AC007919.1, LINC02068, SLC31A1P1, NCEH1, AC007919.2, RNU6-547P, AC108667.2, ECT2, SNORA72, RNU4-4P, ATP5MC1P4, AC108667.1, SPATA16, AC068759.1, NLGN1, AC092967.1, NLGN1-AS1.
- chr5:130,989,897–133,224,413, 72 genes, copy number 5–7 (broad region; genes not listed).
- chr5:138,946,724–140,662,480, 72 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr6:42,696,598–44,553,281, 89 genes, copy number 5–6 (broad region; genes not listed).
- chr7:90,245,174–92,401,383, 33 genes, copy number 5–7 (within-gene range 3–7): CFAP69, Y_RNA, AC002064.2, AC002064.1, FAM237B, GTPBP10, AC002064.3, CLDN12, AC006153.1, CDK14, AC002456.2, AC002456.1, TVP23CP1, AC002458.1, PTP4A1P3, FZD1, AC079760.2, NIPA2P1, AC079760.1, AC000058.1, MTERF1, AC003086.1, AKAP9, CYP51A1, AC000120.2, AC000120.3, CYP51A1-AS1, LRRD1, KRIT1, AC000120.1, Y_RNA, MIR1285-1, ANKIB1.
- chr7:98,106,862–100,065,040, 63 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr7:105,565,120–107,202,522, 25 genes, copy number 7: EFCAB10, AC073073.2, YBX1P2, ATXN7L1, AC005099.1, CDHR3, AC004836.1, SYPL1, DCAF13P1, RNU6-392P, NAMPT, AC007032.1, LARP1BP2, AC004917.1, AC005050.3, AC005050.1, AC005050.2, CCDC71L, LINC02577, RNA5SP236, PIK3CG, PRKAR2B, PRKAR2B-AS1, HBP1, AC004492.1.
- chr7:114,414,244–116,954,334, 35 genes, copy number 6–12: AC073626.1, AC003992.1, RNA5SP238, MIR3666, MDFIC, LINC01393, LINC01392, RAC1P6, Y_RNA, POLR2DP2, SNORA25B, AC092590.1, AC093714.1, AC093714.2, Y_RNA, TFEC, AC073130.3, TES, AC073130.2, AC002066.1, AC073130.1, CAV2, Metazoa_SRP, CAV1, AC006159.1, AC006159.2, COMETT, MET, CAPZA2, AC002543.1, Y_RNA, RNA5SP239, ST7-AS1, AC106873.5, AC106873.7.
- chr7:122,676,580–125,482,966, 39 genes, copy number 5 (within-gene range 3–5): AC006463.1, RPS26P31, RNF133, RNF148, AC004986.1, TAS2R16, AC073311.1, SLC13A1, LYPLA1P1, IQUB, AC073323.1, RNU6-296P, NDUFA5, ASB15, ASB15-AS1, LMOD2, WASL, WASL-DT, RNU6-11P, HYAL6P, HYAL4, SPAM1, AC004690.1, AC004690.2, TMEM229A, AC006148.1, AC006148.2, AC004930.1, SSU72P8, AC005521.1, RNU6-102P, AC004925.1, GPR37, C7orf77, POT1, POT1-AS1, EEF1GP1, LINC02830, AC019155.1.
- chr7:129,953,234–132,087,992, 58 genes, copy number 7: AC073320.1, Y_RNA, ZC3HC1, RNA5SP245, KLHDC10, AC087071.1, TMEM209, AC087071.2, SSMEM1, AC024085.1, CPA2, CPA4, CPA5, CPA1, CEP41, AC007938.1, MESTIT1, MEST, AC007938.5, AC007938.6, AC007938.4, AC007938.2, MIR335, COPG2, AC007938.3, AUXG01000058.1, RNA5SP246, AC234644.1, TSGA13, AC234644.2, KLF14, AC016831.5, AC016831.6, AC016831.2, H4P1, AC016831.3, LINC00513, MIR29A, AC016831.1, MIR29B1, AC016831.4, AC058791.1, LINC-PINT, RNU6-1010P, MKLN1, AC009362.1, MKLN1-AS, AC008264.2, PODXL, AC008264.1, EEF1B2P6, AC093106.1, AC093106.2, NDUFB9P2, CAPZA1P4, AC009518.2, AC009518.1, AC105443.1.
- chr7:138,298,088–140,179,640, 39 genes, copy number 5: AC008155.1, PTMAP10, IMPDH1P3, TRIM24, RPS3AP28, SVOPL, AC013429.2, AC013429.1, AC020983.1, UQCRFS1P2, ATP6V0A4, TMEM213, KIAA1549, RNU6-1272P, ZC3HAV1L, ZC3HAV1, AC018644.1, TTC26, AC009220.2, AC009220.3, AC009220.1, MZT1P2, UBN2, RNU6-206P, FMC1, LUC7L2, FMC1-LUC7L2, AC083880.1, RNU6-911P, KLRG2, AC005531.1, CLEC2L, ERHP1, HIPK2, TBXAS1, PARP12, KDM7A, Y_RNA, KDM7A-DT.
- chr8:79,259,402–80,595,703, 34 genes, copy number 5–8: AC138646.1, AC100870.1, RPL3P9, STMN2, AC016240.1, HEY1, LINC01607, AC036214.1, RNU7-85P, AC036214.4, MRPS28, AC036214.3, AC036214.2, AC009686.2, TPD52, AC009686.1, RN7SL41P, MIR5708, AC104212.3, AC034114.2, AC104212.2, AC104212.1, AC034114.1, RNU6-1213P, AC009812.1, Y_RNA, ZBTB10, AC009812.3, AC009812.4, RPSAP47, RNU7-174P, AC009812.2, RNU2-71P, SLC25A51P3.
- chr8:93,729,356–96,611,790, 69 genes, copy number 5–8 (broad region; genes not listed).
- chr8:121,612,116–123,815,452, 48 genes, copy number 5–11: HAS2, HAS2-AS1, LINC02855, AC037486.1, MRPS36P3, SMILR, LINC01151, AC108136.1, AC100872.1, AC100872.2, CDK5P1, AC016405.3, AC016405.2, ZHX2, AC016405.1, AC104316.2, AC104316.1, DERL1, TBC1D31, HMGB1P19, AC068228.3, FAM83A, U3, AC068228.1, AC068228.2, FAM83A-AS1, MIR4663, C8orf76, ZHX1-C8orf76, UBA52P5, ZHX1, RNU6-628P, AC018992.1, ATAD2, RNU6-875P, MIR548AA1, MIR548D1, DUTP2, IMPDH1P6, NTAQ1, U4, FBXO32, AC090193.1, RN7SKP155, AC135166.1, KLHL38, ANXA13, FAM91A1.
- chr8:131,432,776–133,326,404, 22 genes, copy number 5: SNORA72, AC060788.1, EFR3A, OC90, AC100868.1, HHLA1, KCNQ3, HPYR1, LRRC6, TMEM71, AF228727.1, PHF20L1, AF230666.2, AF230666.1, TG, AF305872.1, SLA, MIR7848, PTCSC1, CCN4, NDRG1, KC877373.1.
- chr9:33,730,345–35,610,041, 87 genes, copy number 5 (broad region; genes not listed).
- chr11:65,422,774–67,261,545, 121 genes, copy number 5 (broad region; genes not listed).
- chr11:68,870,664–70,385,312, 49 genes, copy number 5–6 (within-gene range 4–6): LINC02701, MRPL21, IGHMBP2, AP000808.1, MRGPRD, AP003071.4, AP003071.3, MRGPRF, MRGPRF-AS1, TPCN2, AP003071.5, MIR3164, AP003071.1, AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2.
- chr11:71,382,601–72,479,237, 65 genes, copy number 5 (broad region; genes not listed).
- chr11:125,940,496–126,355,587, 21 genes, copy number 5: AP000842.1, VSIG10L2, CDON, NAP1L1P1, AP000821.1, AP000821.2, AP001893.3, AP001893.2, RPUSD4, AP001893.1, FAM118B, RNU4-86P, RN7SL351P, SRPRA, FOXRED1, RPL35AP26, TIRAP, AP001318.1, AP001318.2, DCPS, GSEC.
- chr12:42,929,848–45,117,888, 27 genes, copy number 5: AC068802.1, AC012038.2, AC012038.1, MRPS36P5, LINC02461, ADAMTS20, AC090525.1, AC090525.2, AC090525.3, EEF1A1P17, PUS7L, AC093012.1, IRAK4, TWF1, TMEM117, ZNF75BP, AC025030.2, AC025030.1, AC025253.1, AC025253.2, NELL2, Y_RNA, DBX2, AC008127.1, RACGAP1P1, SSBL3P, RNA5SP361.
- chr12:68,610,855–69,855,363, 39 genes, copy number 6 (within-gene range 2–6): RAP1B, RPL10P12, SNORA70G, ATP5PDP4, AC090061.1, RPL7P42, NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2.
- chr14:49,570,984–50,335,558, 41 genes, copy number 5: RPS29, RPL32P29, RN7SL1, Y_RNA, LRR1, RHOQP1, AL139099.3, RPL36AL, MGAT2, AL139099.1, DNAAF2, AL139099.2, POLE2, STK16P1, AL591767.2, RNU6ATAC30P, KLHDC1, AL591767.1, KLHDC2, NEMF, Y_RNA, RNU6-539P, RN7SL3, AL627171.2, RN7SL2, AL627171.1, ARF6, RNU6-189P, Metazoa_SRP, LINC01588, MIR6076, PDLIM1P1, AL117692.1, RN7SKP193, Y_RNA, VCPKMT, SOS2, L2HGDH, MIR4504, DMAC2L, AL359397.2.
- chr14:63,204,114–64,750,249, 42 genes, copy number 5 (within-gene range 2–5): RHOJ, AL049871.1, GPHB5, PPP2R5E, AL132992.1, AL136038.3, AL136038.1, GCATP1, WDR89, AL136038.2, HSPE1P2, RNU6-597P, Y_RNA, RNU6-1162P, AL136038.4, U3, SGPP1, EIF2S2P1, RNU7-116P, SYNE2, AL161670.1, RPS28P1, Y_RNA, ESR2, MIR548H1, AL161756.1, TEX21P, AL161756.3, AL161756.2, MTHFD1, AL122035.1, AL122035.2, ZBTB25, AKAP5, ZBTB1, AL049869.2, AL049869.3, HSPA2, PPP1R36, AL049869.1, NUP50P1, PLEKHG3.
- chr16:86,595,189–87,404,779, 25 genes, copy number 5: AC009108.4, AC009108.2, AC009154.1, AC009154.2, LINC02188, LINC02189, AC130467.1, AC093519.2, AC093519.1, LINC02181, AC106745.1, C16orf95, AC136285.3, AC136285.1, AC136285.2, AC010531.4, AC010531.2, AC010531.8, AC010531.1, AC010531.6, AC010531.7, FBXO31, AC010531.5, MAP1LC3B, AC010531.3.
- chr17:59,137,758–60,666,280, 64 genes, copy number 6 (broad region; genes not listed).
- chr19:1,874,871–2,269,759, 25 genes, copy number 5 (within-gene range 3–5): AC012615.1, AC012615.5, ABHD17A, SCAMP4, ADAT3, CSNK1G2, CSNK1G2-AS1, BTBD2, AC005306.1, AC004678.2, AC004678.1, AC007136.1, MKNK2, MOB3A, IZUMO4, AP3D1, DOT1L, AC004490.1, PLEKHJ1, MIR1227, MIR6789, SF3A2, AMH, MIR4321, JSRP1.
- chr19:3,224,661–4,224,814, 48 genes, copy number 5 (within-gene range 3–5): CELF5, AC010649.1, NFIC, AC007792.1, AC005514.1, SMIM24, AC005551.1, DOHH, FZR1, AC005787.1, MFSD12, C19orf71, AC005786.3, AC005786.2, AC005786.4, AC005786.1, HMG20B, GIPC3, TBXA2R, CACTIN-AS1, CACTIN, PIP5K1C, AC004637.1, TJP3, APBA3, AC005954.2, AC005954.1, MRPL54, RAX2, AC005777.1, MATK, ZFR2, FTLP5, ATCAY, RN7SL202P, NMRK2, DAPK3, MIR637, EEF2, SNORD37, PIAS4, ZBTB7A, AC016586.1, MAP2K2, Metazoa_SRP, CREB3L3, SIRT6, ANKRD24.
- chr22:19,969,896–20,408,461, 29 genes, copy number 5: ARVCF, TANGO2, MIR185, AC006547.1, AC006547.3, Metazoa_SRP, DGCR8, MIR3618, MIR1306, AC006547.2, TRMT2A, MIR6816, RANBP1, SNORA77B, ZDHHC8, CCDC188, AC007663.2, LINC00896, RTN4R, MIR1286, AC007663.1, DGCR6L, AC007663.4, AC007663.3, FAM230G, AC007731.2, AC007731.5, USP41, ZNF74.

Autosomal genes at a single copy (total copy number 1): 1,102. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
